Somatic mutation profile of tumor specimen TCGA-ZF-A9RF-01A (aliquot TCGA-ZF-A9RF-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9RF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.7 years (27,281 days).
Specimen TCGA-ZF-A9RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6872b987-427c-4bf3-bdd5-34f57e2cd2e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RF-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RF-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c9f1ca9-fd10-4463-bcc7-f8b5386ac1cf

The open-access MAF lists 277 somatic variants for this specimen: 213 protein-altering or splice-affecting, 52 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 52, Nonsense Mutation 14, Frame Shift Del 5, Splice Site 5, Intron 5, RNA 3, In Frame Del 2, Frame Shift Ins 2, 5'UTR 2, 5'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.5158dup p.S1720Ffs*7 | Frame Shift Ins (INS) | VAF 29/72 reads (40%) | catalogued as rs80359489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.4021C>T p.Q1341* | Nonsense Mutation (SNP) | VAF 39/160 reads (24%) | catalogued as rs137854559, COSV62194083; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- AADAT | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs200677642, COSV61787530; called by muse, mutect2, varscan2
- AC004593.2 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV56091213, COSV56096099; called by muse, mutect2, varscan2
- ACAA1 | c.1197G>C p.K399N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV57173445; called by muse, mutect2, varscan2
- ADA | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM920006, COSV63068837; called by muse, mutect2, varscan2
- ADAM2 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99697337; called by muse, mutect2, varscan2
- AGGF1 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57228709; called by muse, mutect2, varscan2
- AHNAK | c.2435A>T p.N812I | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57211523; called by muse, mutect2, varscan2
- AHNAK2 | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 143/433 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs776549092, COSV60913847; called by muse, mutect2, varscan2
- AKR1C3 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65910343; called by muse, mutect2, varscan2
- ALPK2 | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64492460, COSV64493396; called by muse, mutect2, varscan2
- ANKRD17 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV58219117; called by muse, mutect2, varscan2
- ARFGEF2 | c.1706C>G p.S569C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100904260, COSV64211074; called by muse, mutect2
- ARID1A | c.3935C>A p.S1312Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV61376074; called by muse, varscan2
- ARID1A | c.4371C>G p.F1457L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV61376080; called by muse, mutect2, varscan2
- ARID1A | c.5112C>G p.F1704L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV61376081; called by muse, varscan2
- ARNT | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62230430; called by muse, mutect2, varscan2
- ASCL1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs372191664; called by mutect2, varscan2
- ASPG | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV71933745; called by muse, mutect2, varscan2
- ATM | c.8138G>A p.R2713K | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs876659351, COSV53739675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A1 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as COSV55190901; called by muse, mutect2, varscan2
- ATXN1 | c.2377C>G p.L793V | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV55214633; called by muse, mutect2, varscan2
- BOD1L1 | c.3052G>C p.D1018H | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV50010364, COSV99238329; called by muse, mutect2, varscan2
- BTD | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100329591; called by muse, mutect2, varscan2
- C14orf39 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV58781388; called by muse, mutect2
- C2orf16 | c.1352C>G p.T451R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV68645897; called by muse, mutect2, varscan2
- C6 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.899); catalogued as COSV54709179; called by muse, mutect2, varscan2
- CADM4 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as COSV55928630; called by muse, mutect2, varscan2
- CD1A | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775233831, COSV56860577, COSV56861479; called by muse, mutect2, varscan2
- CDC123 | c.237G>A p.T79= | Splice Region (SNP) | VAF 21/56 reads (38%) | catalogued as rs758301266, COSV55397487; called by muse, mutect2, varscan2
- CEP19 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV56359123, COSV99582493; called by muse, mutect2, varscan2
- CFAP44 | c.2185A>T p.K729* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99869564; called by muse, mutect2, varscan2
- CLDN8 | c.190T>C p.C64R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54525823; called by muse, mutect2, varscan2
- CLEC4F | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs149379407; called by muse, mutect2, varscan2
- CLSTN1 | c.2191C>T p.H731Y (on ENST00000377298 / NM_001009566.3; = p.H721Y on NM_014944.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63647788; called by muse, mutect2, varscan2
- COL22A1 | c.4417G>T p.G1473W | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as COSV57333771, COSV57338092; called by muse, mutect2, varscan2
- COPS2 | c.738G>C p.L246F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54645022; called by muse, mutect2
- CRTC1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs1454418141, COSV58718253; called by muse, mutect2, varscan2
- CYP4F3 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV55409223; called by muse, mutect2, varscan2
- DDX27 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV65596557; called by muse, mutect2, varscan2
- DMD | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 33/54 reads (61%) | catalogued as CM021979, COSV99922489; called by muse, mutect2, varscan2
- DNAJC22 | c.539T>A p.V180E | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV67711757; called by muse, mutect2, varscan2
- DNMT3A | c.926G>C p.R309P | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1553414043, COSV53048863, COSV53067843; called by muse, mutect2, varscan2
- DNTTIP2 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63283963; called by muse, mutect2, varscan2
- DPH1 | c.1086+1G>A p.X362_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as rs1164360598, COSV53984336; called by muse, mutect2, varscan2
- DST | c.5921G>C p.G1974A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV55009944, COSV55014765; called by muse, mutect2, varscan2
- EIF4A2 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56216670; called by muse, mutect2, varscan2
- EPCAM | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55392951; called by muse, mutect2, varscan2
- ERBB2 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV54068645, COSV99508444; called by muse, mutect2, varscan2
- ESAM | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54034480; called by muse, mutect2, varscan2
- EVPL | c.2332G>T p.D778Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767048044, COSV56909996; called by muse, mutect2, varscan2
- EXOC2 | c.2674G>T p.D892Y | Missense Mutation (SNP) | VAF 156/235 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV57864138; called by muse, mutect2, varscan2
- FBN1 | c.5935C>G p.L1979V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.082); catalogued as COSV100355308, COSV57314883; called by muse, mutect2, varscan2
- FBXL7 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV61644933; called by muse, mutect2, varscan2
- FBXW12 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV56483571; called by muse, mutect2, varscan2
- FLG2 | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV66168151; called by muse, mutect2, varscan2
- FLRT2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV58140263, COSV58140305; called by muse, mutect2, varscan2
- FNDC1 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51936280; called by muse, varscan2
- FUT6 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV54605515; called by muse, mutect2, varscan2
- FXYD5 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV61568547; called by muse, mutect2, varscan2
- GALNTL5 | c.1161G>A p.W387* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs1332980459, COSV101217814; called by muse, mutect2, varscan2
- GCFC2 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV58080744; called by muse, mutect2, varscan2
- GNB1L | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765606321, COSV61548349; called by muse, mutect2, varscan2
- GOLM2 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1567025281, COSV55461811; called by muse, mutect2, varscan2
- GPATCH2 | c.1352G>C p.G451A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV65130631, COSV65133312; called by muse, mutect2, varscan2
- GPR158 | c.2470G>T p.V824L | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV66268721, COSV66268889; called by muse, mutect2, varscan2
- GPR39 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61416305; called by muse, mutect2, varscan2
- HAO2 | c.14G>C p.C5S | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV58039120; called by muse, mutect2, varscan2
- HDC | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV51069680; called by muse, mutect2, varscan2
- HECTD4 | c.6379G>C p.E2127Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101107516, COSV66396221; called by muse, mutect2
- HHLA2 | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV63316669, COSV63316866; called by muse, mutect2, varscan2
- HIVEP2 | c.5701G>A p.E1901K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50009520; called by muse, mutect2, varscan2
- HLA-DMB | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1465081585, COSV66870722; called by muse, mutect2, varscan2
- HSD17B6 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100444399, COSV59107673; called by muse, mutect2, varscan2
- HSD3B1 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52490387; called by muse, mutect2, varscan2
- HSPA12B | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54769541, COSV99654003; called by muse, varscan2
- ICE2 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.629); catalogued as COSV55030931, COSV55031501; called by muse, mutect2, varscan2
- IFI35 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV55896227; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 131/405 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); catalogued as rs747636311; called by muse, mutect2, varscan2
- IL15RA | c.796del p.H266Tfs*11 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as COSV101181706; called by mutect2, pindel, varscan2
- IPO5 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as COSV55154049; called by muse, mutect2, varscan2
- IPO9 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1025197001, COSV64233483; called by muse, mutect2, varscan2
- IRAG1 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.543); catalogued as COSV70210714; called by muse, mutect2
- IRS4 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64533884; called by muse, mutect2
- ITSN2 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs761709930, COSV61946185; called by muse, mutect2, varscan2
- KCNH1 | c.1851C>A p.S617R (on ENST00000271751 / NM_172362.3; = p.S590R on NM_002238.4) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV55078652; called by muse, mutect2, varscan2
- KDM3B | c.3146G>A p.G1049E | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58690015; called by muse, mutect2, varscan2
- KMT2A | c.8947C>T p.P2983S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV63284930; called by muse, mutect2, varscan2
- KMT2A | c.10292C>G p.S3431C | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV63284936; called by muse, mutect2, varscan2
- L1CAM | c.1830G>A p.G610= | Splice Region (SNP) | VAF 24/43 reads (56%) | catalogued as rs1214205620, COSV62827827; called by muse, mutect2, varscan2
- LAP3 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV56899554; called by muse, mutect2, varscan2
- LCOR | c.3446G>T p.W1149L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53715484; called by muse, mutect2, varscan2
- LENEP | c.95T>C p.M32T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs752377547, COSV52696728; called by muse, mutect2
- LGSN | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65727004; called by muse, mutect2, varscan2
- LIN54 | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1296297397, COSV61200894; called by muse, mutect2, varscan2
- LMNA | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV100738678; called by muse, mutect2, varscan2
- LMNTD2 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54240279; called by muse, mutect2, varscan2
- LPA | c.3367T>A p.W1123R | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as COSV60300873; called by muse, mutect2, varscan2
- LRRC8B | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as COSV58374471; called by muse, mutect2, varscan2
- MADD | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV60623357; called by muse, mutect2, varscan2
- MAGEB18 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as rs1252497703, COSV100305463; called by muse, mutect2, varscan2
- MAP3K14 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV100766487; called by muse, mutect2, varscan2
- MATN1 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65650497; called by muse, mutect2, varscan2
- MDGA2 | c.1972G>A p.D658N (on ENST00000399232 / NM_001113498.2; = p.D360N on NM_182830.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62088612; called by muse, mutect2, varscan2
- MED23 | c.1312A>G p.N438D | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.334); catalogued as COSV63432131; called by muse, mutect2, varscan2
- MSH2 | c.1373T>C p.L458S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs63750521, CM941066, COSV51878383; called by muse, mutect2, varscan2
- MTOR | c.2967C>A p.F989L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV63869345, COSV63870438; called by muse, mutect2, varscan2
- MYB | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100214859; called by muse, mutect2, varscan2
- MYH2 | c.2403C>G p.F801L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as COSV55431132, COSV55436414, COSV55450781; called by muse, mutect2, varscan2
- MYO6 | c.1095G>C p.K365N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.265); catalogued as rs772438082, COSV64118731; called by muse, varscan2
- NAV3 | c.4807G>A p.E1603K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57075607; called by muse, mutect2, varscan2
- NCAPD3 | c.2700G>T p.E900D | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs142260444; called by muse, mutect2
- NCAPD3 | c.2698G>T p.E900* | Nonsense Mutation (SNP) | VAF 58/98 reads (59%) | catalogued as COSV101599366; called by muse, mutect2
- NDUFAB1 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50287224; called by muse, mutect2, varscan2
- NELL2 | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61573356; called by muse, mutect2, varscan2
- NF1 | c.5187del p.T1730Pfs*4 (on ENST00000358273 / NM_001042492.3; = p.T1709Pfs*4 on NM_000267.3) | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as CD910541; called by mutect2, pindel, varscan2
- NFIC | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV100545340; called by muse, mutect2
- NISCH | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100617338; called by muse, mutect2, varscan2
- NKTR | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51771023; called by muse, mutect2, varscan2
- NMI | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54638509; called by muse, mutect2, varscan2
- NUP155 | c.1606G>A p.E536K (on ENST00000231498 / NM_153485.3; = p.E477K on NM_004298.4) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as COSV51529273; called by muse, mutect2, varscan2
- OR10J5 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58385800; called by muse, mutect2, varscan2
- OR4C46 | c.743T>C p.F248S | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.192); catalogued as COSV60219038; called by muse, mutect2, varscan2
- OR5D16 | c.568T>C p.S190P | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65721762; called by muse, mutect2, varscan2
- PAPPA2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as COSV100866512, COSV62777007; called by muse, mutect2
- PAPPA2 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62777013; called by muse, mutect2, varscan2
- PATJ | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1404651157, COSV57160564; called by muse, mutect2, varscan2
- PCDH12 | c.1201A>G p.R401G | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51520950; called by muse, mutect2, varscan2
- PCDHGA3 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.376); catalogued as COSV54022213; called by muse, mutect2, varscan2
- PCDHGA4 | c.638T>G p.V213G | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99538493; called by muse, mutect2
- PDE6B | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs749225833, COSV55325767; called by muse, mutect2, varscan2
- PHF11 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV62896417; called by muse, mutect2, varscan2
- PIK3C2G | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as COSV56806477; called by muse, mutect2, varscan2
- PIK3C2G | c.2979G>A p.M993I (on ENST00000676171; = p.M952I on NM_004570.5) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs184145959, COSV56806498; called by muse, mutect2, varscan2
- PLCG2 | c.1921C>G p.H641D | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs573799583, COSV63868937; called by muse, mutect2, varscan2
- PLXNA4 | c.2827G>T p.A943S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV58119781; called by muse, mutect2, varscan2
- POU4F3 | c.377C>A p.T126K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs761199052, COSV57943184, COSV57943608; called by muse, mutect2, varscan2
- PRKRIP1 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs1205784434, COSV61349805; called by muse, mutect2, varscan2
- PTPN20 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as rs1555161632; called by muse, mutect2, varscan2
- PTPRD | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); catalogued as COSV61940670; called by muse, mutect2, varscan2
- PTX4 | c.1436G>C p.*479Sext*? (on ENST00000447419 / NM_001328608.2; = p.*474Sext*? on NM_001013658.1) | Nonstop Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99560469; called by muse, mutect2, varscan2
- QRICH2 | c.2894C>G p.P965R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53152731; called by muse, mutect2, varscan2
- RASGRF2 | c.2470G>T p.A824S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV54128217; called by muse, mutect2
- RB1 | c.1811A>G p.D604G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57304305; called by muse, mutect2, varscan2
- RBM6 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1476118469, COSV56482151; called by muse, mutect2, varscan2
- RNF144A | c.280A>G p.K94E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV57982025; called by muse, mutect2, varscan2
- S100A14 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV59884587; called by muse, mutect2, varscan2
- SACS | c.4021C>T p.L1341F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.25); catalogued as COSV66538779; called by muse, mutect2, varscan2
- SCN1A | c.5145C>G p.I1715M (on ENST00000303395 / NM_001202435.3; = p.I1704M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1559104174, COSV57668010; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6D | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs1288447869, COSV60376058, COSV60381600; called by muse, mutect2, varscan2
- SERPINC1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as CM990200, COSV62929226; called by muse, mutect2, varscan2
- SEZ6L | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV50662154; called by muse, mutect2, varscan2
- SLC22A10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763527938, COSV60421090; called by muse, mutect2, varscan2
- SLC27A3 | c.787C>T p.P263S (on ENST00000271857; = p.P135S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1459712406, COSV55163248; called by muse, mutect2, varscan2
- SLC2A4 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.03); catalogued as rs750521517, COSV50300776; called by muse, mutect2, varscan2
- SLC38A3 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.297); catalogued as COSV101309933; called by muse, mutect2, varscan2
- SLC4A3 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV56093125, COSV99813113; called by muse, mutect2, varscan2
- SLC4A8 | c.2363T>C p.I788T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV60651153; called by muse, mutect2, varscan2
- SLC6A11 | c.1759T>A p.L587M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as COSV54392711; called by muse, mutect2, varscan2
- SLC6A11 | c.1892A>G p.H631R | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV54392724; called by muse, mutect2, varscan2
- SMARCA4 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.555); catalogued as rs765989895, COSV60792142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCR8 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58176850; called by muse, mutect2, varscan2
- SPON2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52055603, COSV99335239; called by muse, mutect2, varscan2
- SS18 | c.720A>T p.Q240H | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs61731053, COSV52260672; called by muse, mutect2
- SSX7 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 129/198 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV53339772; called by muse, mutect2, varscan2
- STAC | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV56209668, COSV56220399; called by muse, mutect2, varscan2
- STK25 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749783236, COSV57263236; called by muse, mutect2, varscan2
- STX7 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV63398642; called by muse, mutect2, varscan2
- SUSD5 | c.1648G>T p.G550C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100535131; called by muse, mutect2, varscan2
- SVEP1 | c.5900C>T p.P1967L | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1262925142, COSV52838455; called by muse, mutect2, varscan2
- TAF1L | c.1045A>G p.K349E | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV54261053; called by muse, mutect2, varscan2
- TEK | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV66228679; called by muse, mutect2, varscan2
- TMEM140 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs988297687, COSV51966060; called by muse, mutect2, varscan2
- TNXB | c.885C>A p.C295* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs937211615, COSV100926330; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs142777756, COSV61455360; called by muse, mutect2, varscan2
- TRMT12 | c.1222C>G p.Q408E | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60776874; called by muse, mutect2, varscan2
- TRPM6 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV62508298; called by muse, mutect2, varscan2
- TTN | c.60437G>C p.S20146T (on ENST00000591111; = p.S12722T on NM_003319.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | PolyPhen probably damaging (0.991); catalogued as rs1290046297, COSV60005332; called by muse, mutect2, varscan2
- TTN | c.24464G>T p.S8155I (on ENST00000591111; = p.S7228I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen benign (0.229); catalogued as COSV60005360; called by muse, mutect2, varscan2
- UNC13D | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1194073667, COSV52884190; called by muse, mutect2, varscan2
- USH1C | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV50014911, COSV99140070; called by muse, mutect2, varscan2
- USH2A | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.545); catalogued as COSV56359886; called by muse, mutect2, varscan2
- USO1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1471065653, COSV53711456; called by muse, mutect2, varscan2
- UTP4 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as rs781261871, COSV58732623; called by muse, mutect2, varscan2
- VTI1B | c.603-1G>C p.X201_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | catalogued as COSV53619744; called by muse, mutect2, varscan2
- WWTR1 | c.1080C>G p.F360L | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.404); catalogued as COSV62291136, COSV62292125; called by muse, mutect2, varscan2
- YME1L1 | c.1495G>C p.D499H (on ENST00000326799 / NM_139312.3; = p.D442H on NM_014263.4) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58759091; called by muse, mutect2, varscan2
- ZFAND5 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52988557; called by muse, varscan2
- ZFYVE16 | c.4087C>T p.Q1363* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100566393; called by muse, mutect2, varscan2
- ZHX1 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV52876297; called by muse, mutect2, varscan2
- ZIM3 | c.817C>G p.H273D | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54142043; called by muse, mutect2, varscan2
- ZNF382 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53087841; called by muse, mutect2, varscan2
- ZNF454 | c.1542T>A p.H514Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60768123; called by muse, mutect2, varscan2
- ZNF569 | c.1301G>C p.R434T | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV57594912; called by muse, mutect2
- ZNF785 | c.786G>T p.K262N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV67876279; called by muse, mutect2, varscan2
- ZNF98 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs770119901, COSV100757460; called by muse, mutect2, varscan2
- ZNFX1 | c.1715G>C p.R572T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV65574909; called by muse, mutect2, varscan2
- ZSWIM1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs747287995, COSV54846952; called by muse, mutect2, varscan2
- ZSWIM5 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | catalogued as rs772056953, COSV62737639; called by muse, mutect2, varscan2
- ARHGEF11 | c.3322del p.T1108Hfs*5 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, varscan2
- COBLL1 | c.345-16_348del p.X115_splice (on ENST00000392717; = p.X77_splice on NM_014900.5) | Splice Site (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- CWC27 | c.117_138del p.N39Kfs*17 | Frame Shift Del (DEL) | VAF 27/184 reads (15%) | called by mutect2, pindel
- DNAAF1 | c.764del p.N255Tfs*18 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, pindel*, varscan2
- IGKV1D-16 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INSC | c.544-10_554del p.X182_splice | Splice Site (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- NBPF9 | c.120G>C p.E40D | Missense Mutation (SNP) | VAF 37/419 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2
- PABPC1 | c.1220_1234del p.G407_A411del | In Frame Del (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
- SLC25A13 | c.625_626dup p.T210Vfs*41 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- SLC8A1 | c.2085_2099del p.R696_E700del | In Frame Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel
- SYNE1 | c.12795-16_12798del p.X4265_splice (on ENST00000367255 / NM_182961.4; = p.X4194_splice on NM_033071.3) | Splice Site (DEL) | VAF 12/123 reads (10%) | called by mutect2, pindel
- ACACA | c.5403C>T p.L1801= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as rs757250697; called by muse, mutect2, varscan2
- ADA | c.648G>T p.G216= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV63068840; called by muse, mutect2, varscan2
- ADCK2 | c.195G>A p.L65= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV50781153; called by muse, mutect2, varscan2
- ADGRB1 | c.2590C>T p.L864= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as rs1181957617, COSV60095403; called by muse, mutect2, varscan2
- ALDH16A1 | c.2193C>T p.R731= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as rs1189083356, COSV53193759; called by muse, mutect2, varscan2
- ALPK1 | c.975G>A p.L325= | Silent (SNP) | VAF 107/131 reads (82%) | catalogued as COSV51584344; called by muse, mutect2, varscan2
- ATAD1 | c.513G>A p.Q171= | Silent (SNP) | VAF 83/149 reads (56%) | catalogued as rs1481830456, COSV57756642; called by muse, mutect2, varscan2
- ATP13A1 | c.3555C>T p.L1185= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99179277; called by muse, mutect2
- CDH18 | c.636T>C p.P212= | Silent (SNP) | VAF 25/198 reads (13%) | catalogued as rs1160382346, COSV56917365; called by muse, mutect2, varscan2
- CELF4 | c.780C>T p.A260= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV58451814; called by muse, mutect2, varscan2
- CENPI | c.1848C>T p.A616= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs143412234, COSV54501957; called by muse, mutect2, varscan2
- CEP250 | c.510G>A p.L170= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs1267947341, COSV61169545; called by muse, mutect2, varscan2
- CFAP44 | c.2184G>A p.E728= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV55610792; called by muse, mutect2, varscan2
- CLRN2 | c.621G>C p.A207= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV71825198, COSV71825248; called by muse, mutect2, varscan2
- DNAI1 | c.1035G>A p.R345= | Silent (SNP) | VAF 43/181 reads (24%) | catalogued as COSV54280537; called by muse, mutect2, varscan2
- DUSP5 | c.891G>A p.R297= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV63645714; called by muse, mutect2, varscan2
- ERBB2 | c.2160G>C p.L720= | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as rs1349763403; called by muse, mutect2
- FBXL16 | c.474G>A p.V158= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV60964344; called by muse, mutect2, varscan2
- GCOM1 | c.396C>T p.L132= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV51089871; called by muse, mutect2, varscan2
- GPHB5 | c.255C>T p.T85= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs768349032, COSV100030206; called by muse, varscan2
- HNRNPM | c.1794G>T p.P598= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1470613944, COSV55313315; called by muse, mutect2, varscan2
- HSPA12A | c.1884C>G p.L628= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV65021973; called by muse, mutect2, varscan2
- ITGB7 | c.2130C>T p.V710= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs755930937, COSV57238492; called by muse, mutect2, varscan2
- KATNIP | c.4221C>T p.L1407= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV55179001; called by muse, mutect2, varscan2
- KIFAP3 | c.636A>G p.G212= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1454086975, COSV63033198; called by muse, mutect2, varscan2
- KRT5 | c.1188G>A p.L396= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV52860256; called by muse, mutect2, varscan2
- MAPK15 | c.1506C>T p.F502= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV62028050; called by muse, mutect2
- MYH7B | c.1362C>T p.Y454= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs754743371, COSV53419083; called by muse, mutect2, varscan2
- OR13C2 | c.819G>A p.L273= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV73377688; called by muse, mutect2, varscan2
- OR52A1 | c.618C>A p.A206= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs1469918750, COSV61092336; called by muse, mutect2, varscan2
- PCDHA13 | c.1773G>T p.V591= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV56495455; called by muse, mutect2, varscan2
- PCSK6 | c.882C>T p.I294= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV59340227; called by muse, mutect2, varscan2
- PDE3A | c.2022C>A p.P674= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs754823322, COSV62971619; called by muse, mutect2, varscan2
- PKN3 | c.2313C>T p.I771= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as rs367711893; called by muse, mutect2, varscan2
- PLCH2 | c.1653A>T p.G551= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV53941903; called by muse, mutect2, varscan2
- PLCL1 | c.2328T>C p.P776= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV70827035; called by muse, mutect2, varscan2
- PLEKHG6 | c.282C>T p.S94= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV50599723; called by muse, mutect2, varscan2
- POC5 | c.1188A>G p.E396= (on ENST00000428202 / NM_001099271.2; = p.E371= on NM_152408.2) | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV66842107; called by muse, mutect2, varscan2
- PSG4 | c.321G>T p.L107= | Silent (SNP) | VAF 55/242 reads (23%) | catalogued as COSV54932921; called by muse, mutect2, varscan2
- RALY | c.717C>T p.S239= (on ENST00000246194 / NM_016732.3; = p.S223= on NM_007367.4) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs574662614, COSV55781310, COSV99865818; called by muse, mutect2
- ROS1 | c.1428C>T p.V476= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV63854295; called by muse, mutect2, varscan2
- RPP25L | c.255C>T p.T85= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV52407118; called by muse, mutect2, varscan2
- SACS | c.11511G>A p.Q3837= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV66538770; called by muse, mutect2, varscan2
- SCAMP3 | c.1032C>T p.F344= | Silent (SNP) | VAF 44/156 reads (28%) | catalogued as COSV56944838; called by muse, mutect2, varscan2
- SFMBT2 | c.1860C>T p.D620= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV62808657; called by muse, mutect2, varscan2
- TENM3 | c.198G>A p.L66= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs781748652, COSV69305791, COSV69311915; called by muse, mutect2, varscan2
- TRPM3 | c.2925C>A p.V975= (on ENST00000357533 / NM_001366142.2; = p.V818= on NM_020952.6) | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV62584699; called by muse, mutect2, varscan2
- UBR2 | c.5166G>A p.K1722= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV65749877; called by muse, mutect2, varscan2
- UNC13D | c.2358G>C p.L786= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV52884179; called by muse, mutect2, varscan2
- VPS26B | c.786C>T p.I262= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV55544843; called by muse, mutect2, varscan2
- WFS1 | c.1521C>G p.L507= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs776745666, COSV56988623; called by muse, mutect2, varscan2
- ZNF648 | c.381C>T p.P127= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV60570577; called by muse, mutect2, varscan2
- ASIC2 | c.556-179547C>T | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- C3P1 | n.2736C>T | RNA (SNP) | VAF 13/70 reads (19%) | catalogued as rs531964381; called by muse, mutect2, varscan2
- DDHD1 | chr14:53152948 C>T | 5'Flank (SNP) | VAF 3/8 reads (38%) | catalogued as COSV60359333; called by muse, mutect2
- EIF6 | c.107+45C>T | Intron (SNP) | VAF 48/142 reads (34%) | catalogued as COSV65582821; called by muse, mutect2, varscan2
- FUT7 | chr9:137034734 C>T | 5'Flank (SNP) | VAF 18/56 reads (32%) | catalogued as rs778847727; called by muse, mutect2, varscan2
- GABRE | c.784+198A>C | Intron (SNP) | VAF 8/136 reads (6%) | catalogued as COSV100944275; called by muse, mutect2
- GNAO1 | c.723+6916C>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as rs1338366522, COSV52613195; called by muse, mutect2, varscan2
- MIR376A2 | n.24T>A | RNA (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- RBM44 | c.-98-2805C>T | Intron (SNP) | VAF 9/13 reads (69%) | catalogued as rs1412674984, COSV100389861; called by muse, mutect2, varscan2
- SNORD113-2 | n.35C>G | RNA (SNP) | VAF 19/73 reads (26%) | catalogued as rs1423656563; called by muse, mutect2, varscan2
- TTI2 | c.-2G>A | 5'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100659725; called by muse, mutect2, varscan2
- ZNF207 | c.-130C>T | 5'UTR (SNP) | VAF 23/123 reads (19%) | catalogued as rs564135193, COSV58299680; called by muse, mutect2, varscan2
